Somatic mutation profile of tumor specimen 0DPEA0 from CCDI case PBCCVR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.8 years (6,125 days).
Specimen 0DPEA0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3f2c023-39c3-4866-88e2-3eea80031621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPE90 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6f56962-d7ac-4e53-a58e-121ba0986293

The open-access MAF lists 93 somatic variants for this specimen: 54 protein-altering or splice-affecting, 22 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 22, Intron 8, 5'UTR 4, 3'UTR 3, Nonsense Mutation 3, RNA 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 276/518 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- RP1 | c.2219C>G p.S740* | Nonsense Mutation (SNP) | VAF 80/1028 reads (8%) | catalogued as rs1554519555; ClinVar: likely pathogenic; called by muse, mutect2
- AADACL2 | c.168G>T p.M56I | Missense Mutation (SNP) | VAF 94/821 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV62930537; called by muse, mutect2, varscan2
- C18orf63 | c.213+1G>A p.X71_splice | Splice Site (SNP) | VAF 93/619 reads (15%) | catalogued as rs1329806867; called by muse, mutect2, varscan2
- CDH20 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 49/456 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as rs751531893, COSV53004584; called by muse, mutect2, varscan2
- DPY19L2 | c.2054T>A p.V685E | Missense Mutation (SNP) | VAF 120/1371 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100192738, COSV61040319; called by muse, mutect2, varscan2
- FREM1 | c.1545G>T p.L515F | Missense Mutation (SNP) | VAF 220/1473 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467349846; called by muse, mutect2, varscan2
- HSPA5 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 50/790 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs774390329; called by muse, mutect2
- KCNQ5 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 62/1016 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs776285517, COSV59652775; called by muse, mutect2
- KIF1A | c.4844A>G p.Y1615C (on ENST00000320389 / NM_001379639.1; = p.Y1607C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100240986; called by muse, mutect2, varscan2
- LRP3 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as rs376119682; called by muse, mutect2, varscan2
- NR4A2 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 72/832 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100277404; called by muse, mutect2
- NTN1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 37/820 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1034816738, COSV51486839; called by muse, mutect2
- OR4C13 | c.275T>C p.F92S | Missense Mutation (SNP) | VAF 100/669 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs782706515; called by muse, mutect2, varscan2
- POLR2E | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs369309356; called by muse, mutect2, varscan2
- PTPN11 | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 421/1019 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs397507549, CM055503, COSV61004883, COSV61007076; called by muse, mutect2, varscan2
- ROCK1 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 84/1317 reads (6%) | catalogued as rs768138112; called by muse, mutect2
- SLBP | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 134/742 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59183766; called by muse, mutect2, varscan2
- TSPYL6 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 66/677 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.184); catalogued as rs537805712, COSV100336710, COSV57820000; called by muse, mutect2
- ZFHX4 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 117/776 reads (15%) | catalogued as COSV51491400; called by muse, mutect2, varscan2
- AGRN | c.4969G>A p.D1657N | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- AK9 | c.2747A>C p.E916A | Missense Mutation (SNP) | VAF 137/807 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATF7IP | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 146/1158 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 36/1220 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CFAP74 | c.4365G>C p.K1455N | Missense Mutation (SNP) | VAF 215/533 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CPT1B | c.2091C>G p.F697L | Missense Mutation (SNP) | VAF 167/554 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DDX60 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 122/685 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- EPSTI1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 55/555 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ESCO1 | c.2267G>T p.W756L | Missense Mutation (SNP) | VAF 89/936 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FANCM | c.3224C>G p.S1075C | Missense Mutation (SNP) | VAF 153/924 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FKBP10 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 78/587 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- HLA-DOB | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- KATNAL1 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 100/700 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, varscan2
- KDR | c.3551T>G p.L1184W | Missense Mutation (SNP) | VAF 145/840 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIF26B | c.3993G>T p.E1331D | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MFSD5 | c.793A>C p.I265L | Missense Mutation (SNP) | VAF 62/910 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.306); called by muse, mutect2
- N4BP2 | c.2295dup p.A766Sfs*18 | Frame Shift Ins (INS) | VAF 191/1058 reads (18%) | called by mutect2, varscan2
- OR4S2 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 173/902 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OTUD1 | c.1143G>T p.L381F | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAX8 | c.691C>A p.H231N | Missense Mutation (SNP) | VAF 86/968 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2
- POLD1 | c.2842C>A p.H948N | Missense Mutation (SNP) | VAF 30/722 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- RGS22 | c.2166+6T>C | Splice Region (SNP) | VAF 182/1239 reads (15%) | called by muse, mutect2, varscan2
- RNF175 | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 211/1108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC20A1 | c.1198G>C p.V400L | Missense Mutation (SNP) | VAF 92/971 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.02); called by muse, mutect2
- SLC24A3 | c.1718A>G p.Y573C | Missense Mutation (SNP) | VAF 64/490 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SLC38A3 | c.735C>A p.N245K | Missense Mutation (SNP) | VAF 146/801 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.039); called by mutect2, varscan2
- SLC6A6 | c.1529T>C p.V510A | Missense Mutation (SNP) | VAF 90/327 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- TMCC2 | c.1745A>G p.N582S | Missense Mutation (SNP) | VAF 119/531 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TNR | c.2584A>T p.T862S | Missense Mutation (SNP) | VAF 174/439 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 49/1368 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- TTN | c.102295C>A p.L34099M (on ENST00000591111; = p.L26675M on NM_003319.4) | Missense Mutation (SNP) | VAF 48/827 reads (6%) | PolyPhen benign (0.005); called by muse, mutect2
- UBAP2L | c.3029C>T p.P1010L | Missense Mutation (SNP) | VAF 122/643 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH2A | c.6613C>A p.L2205I | Missense Mutation (SNP) | VAF 119/826 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF275 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 138/354 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAMTS10 | c.3264C>T p.S1088= | Silent (SNP) | VAF 44/331 reads (13%) | called by muse, mutect2, varscan2
- ADIPOQ | c.624C>A p.G208= | Silent (SNP) | VAF 93/693 reads (13%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1977T>G p.V659= | Silent (SNP) | VAF 86/884 reads (10%) | called by muse, mutect2, varscan2
- BST1 | c.96G>A p.A32= | Silent (SNP) | VAF 37/429 reads (9%) | called by muse, mutect2
- CASZ1 | c.480C>T p.S160= | Silent (SNP) | VAF 72/451 reads (16%) | catalogued as rs773590737; called by muse, mutect2, varscan2
- CFAP58 | c.1716A>G p.K572= | Silent (SNP) | VAF 56/1036 reads (5%) | called by muse, mutect2
- FAM171A2 | c.1431G>T p.P477= | Silent (SNP) | VAF 82/537 reads (15%) | called by muse, mutect2, varscan2
- FOXK1 | c.1911C>A p.G637= | Silent (SNP) | VAF 39/453 reads (9%) | called by muse, mutect2
- KLHL1 | c.960C>T p.F320= | Silent (SNP) | VAF 167/1156 reads (14%) | catalogued as rs765444940; called by muse, mutect2, varscan2
- MMEL1 | c.429C>T p.R143= | Silent (SNP) | VAF 87/498 reads (17%) | catalogued as rs139093340, COSV56521232; called by muse, mutect2, varscan2
- OR10Q1 | c.333C>T p.L111= | Silent (SNP) | VAF 27/534 reads (5%) | catalogued as rs929269018, COSV57470633; called by muse, mutect2
- OR4K3 | c.417A>G p.R139= | Silent (SNP) | VAF 100/1188 reads (8%) | called by muse, mutect2
- OR4K5 | c.792C>A p.I264= | Silent (SNP) | VAF 102/1502 reads (7%) | catalogued as COSV60002497; called by muse, mutect2
- OTUD4 | c.1944C>T p.N648= (on ENST00000447906 / NM_001366057.1; = p.N583= on NM_001102653.1) | Silent (SNP) | VAF 134/815 reads (16%) | called by muse, mutect2, varscan2
- PCDHGA9 | c.54G>C p.S18= | Silent (SNP) | VAF 70/760 reads (9%) | catalogued as rs536630249; called by muse, mutect2
- PKP4 | c.1062G>C p.L354= | Silent (SNP) | VAF 271/963 reads (28%) | called by muse, mutect2, varscan2
- PSMA8 | c.255T>A p.T85= | Silent (SNP) | VAF 79/549 reads (14%) | called by muse, mutect2, varscan2
- SLC38A3 | c.261C>T p.L87= | Silent (SNP) | VAF 168/437 reads (38%) | catalogued as rs778946609; called by muse, mutect2, varscan2
- SMYD2 | c.720T>C p.Y240= | Silent (SNP) | VAF 158/896 reads (18%) | catalogued as rs765377935; called by muse, mutect2, varscan2
- TLCD5 | c.219C>G p.L73= (on ENST00000375095 / NM_001198671.2; = p.L95= on NM_174926.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 236/1146 reads (21%) | catalogued as rs913045405; called by muse, mutect2, varscan2
- TNFAIP6 | c.168G>A p.A56= | Silent (SNP) | VAF 82/1129 reads (7%) | catalogued as rs369173073, COSV99693993; called by muse, mutect2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 49/1353 reads (4%) | catalogued as rs1267156464; called by muse, mutect2
- ARID3A | c.1594+51G>A | Intron (SNP) | VAF 23/60 reads (38%) | catalogued as rs1166924982; called by muse, mutect2, varscan2
- BPIFB4 | chr20:33081517 C>A | 5'Flank (SNP) | VAF 112/630 reads (18%) | called by muse, mutect2, varscan2
- CARD9 | c.*79C>T | 3'UTR (SNP) | VAF 76/161 reads (47%) | called by muse, mutect2, varscan2
- CENPJ | c.3301+82C>A | Intron (SNP) | VAF 16/208 reads (8%) | catalogued as COSV67883193; called by muse, mutect2
- CTC1 | c.1946-10C>A | Intron (SNP) | VAF 30/190 reads (16%) | called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 16/158 reads (10%) | called by muse, varscan2
- ILF3 | c.2059+973A>G | Intron (SNP) | VAF 104/653 reads (16%) | catalogued as rs1404690953; called by muse, mutect2, varscan2
- IRGM | c.*129G>T | 3'UTR (SNP) | VAF 80/640 reads (13%) | called by muse, mutect2, varscan2
- LONRF1 | c.-73C>G | 5'UTR (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2, varscan2
- NTM | c.934+2968G>A | Intron (SNP) | VAF 48/673 reads (7%) | catalogued as rs956888511; called by muse, mutect2
- NXNL2 | c.-59del | 5'UTR (DEL) | VAF 3/15 reads (20%) | called by mutect2, varscan2
- POLR1A | c.4780-62C>A | Intron (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- RPGRIP1 | c.1152-14C>T | Intron (SNP) | VAF 35/253 reads (14%) | called by muse, mutect2, varscan2
- RTL8A | c.*385C>G | 3'UTR (SNP) | VAF 104/228 reads (46%) | called by muse, mutect2, varscan2
- RTRAF | c.-45C>A | 5'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- SFN | c.-40C>T | 5'UTR (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- SLC9B1P2 | n.662T>C | RNA (SNP) | VAF 183/962 reads (19%) | called by muse, mutect2, varscan2
